Somatic mutation profile of tumor specimen TCGA-DE-A4M9-01A (aliquot TCGA-DE-A4M9-01A-11D-A257-08) from TCGA case TCGA-DE-A4M9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.4 years (10,384 days).
Specimen TCGA-DE-A4M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb861e6-1dd8-43dc-8fb9-0a9a362ef5db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A4M9-10A (Blood Derived Normal), aliquot TCGA-DE-A4M9-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee11ebef-e44b-4b26-b4f8-14753ff86d55

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.5431A>G p.T1811A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV61735219, COSV61735466; called by muse, mutect2
- CDH7 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as rs780536938, COSV59885635; called by muse, mutect2, varscan2
- FSTL4 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs768871164, COSV54768321; called by muse, mutect2, varscan2
- KRT85 | c.490T>C p.C164R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV57737909; called by muse, mutect2, varscan2
- GPR75 | c.762G>A p.G254= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1319712388, COSV61831056; called by muse, mutect2, varscan2
- SAMD7 | c.828C>T p.D276= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV59420579; called by muse, mutect2, varscan2
- S1PR3 | chr9:88991137 C>G | 5'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as COSV57837130; called by muse, mutect2, varscan2
